Somatic mutation profile of tumor specimen MMRF_2328_1_BM_CD138pos (aliquot MMRF_2328_1_BM_CD138pos_T1_KHS5U_L11044) from MMRF case MMRF_2328, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.4 years (24,245 days).
Specimen MMRF_2328_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4d3c02a-b498-4c20-8bbf-94209226b76f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2328_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2328_1_PB_WBC_C2_KHS5U_L11043; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/402dc6cd-80c9-40fe-a25d-8480c3505583

The open-access MAF lists 88 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 20, 5'UTR 9, Silent 8, Intron 6, 5'Flank 4, Nonsense Mutation 3, Frame Shift Del 2, 3'Flank 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- QDPR | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs750201480, CM951098; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52208183; called by muse, mutect2, varscan2
- AIRE | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs142286875; called by muse, mutect2
- CCDC158 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs368025660; called by muse, mutect2, varscan2
- HECW1 | c.290T>A p.V97D | Missense Mutation (SNP) | VAF 101/207 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV67834603; called by muse, mutect2, varscan2
- IFT122 | c.2393G>A p.R798H (on ENST00000348417 / NM_052989.3; = p.R739H on NM_018262.4) | Missense Mutation (SNP) | VAF 117/416 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs755677495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV2-70 | c.170G>A p.W57* | Nonsense Mutation (SNP) | VAF 78/233 reads (33%) | catalogued as rs374376585; called by muse, mutect2, varscan2
- IGLV3-1 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 87/141 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as rs184648956; called by muse, mutect2, varscan2
- KCNN3 | c.1889A>G p.K630R (on ENST00000618040 / NM_001204087.1; = p.K615R on NM_002249.6) | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.633); catalogued as rs201207460; called by muse, mutect2, varscan2
- RPL18 | c.491+3G>A | Splice Region (SNP) | VAF 43/111 reads (39%) | catalogued as rs1289877387; called by muse, mutect2, varscan2
- SGCZ | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs750754361, COSV66026423; called by muse, mutect2, varscan2
- STRADA | c.1009G>A p.G337S (on ENST00000336174 / NM_001363786.1; = p.G300S on NM_153335.6) | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.84); catalogued as rs772509390; called by muse, mutect2, varscan2
- TTLL11 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs1257841865; called by muse, mutect2
- VANGL2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 36/750 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM1514916, COSV63604879; called by muse, mutect2
- WNT11 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 114/259 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as rs756851051, COSV100490324; called by muse, mutect2, varscan2
- ADGRA2 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ALK | c.524G>A p.S175N | Missense Mutation (SNP) | VAF 188/559 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP350 | c.368A>T p.E123V | Missense Mutation (SNP) | VAF 24/449 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DNAH7 | c.6790_6793dup p.L2265* | Nonsense Mutation (INS) | VAF 109/301 reads (36%) | called by mutect2, pindel, varscan2
- EIF4EBP1 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 70/430 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.098); called by muse, varscan2
- FBXO21 | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 115/313 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FYB1 | c.1410_1411del p.K473Efs*32 | Frame Shift Del (DEL) | VAF 74/194 reads (38%) | called by mutect2, pindel, varscan2
- HASPIN | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 111/262 reads (42%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGF1R | c.1895A>G p.N632S | Missense Mutation (SNP) | VAF 33/764 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- ITGB1BP2 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLLT10 | c.1305T>A p.N435K | Missense Mutation (SNP) | VAF 128/285 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MYH15 | c.2848G>A p.A950T | Missense Mutation (SNP) | VAF 133/459 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- N4BP1 | c.1458C>G p.D486E | Missense Mutation (SNP) | VAF 113/284 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PLCH1 | c.3796A>T p.T1266S (on ENST00000340059 / NM_001130960.2; = p.T1258S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- PTPRB | c.2792del p.G931Vfs*45 | Frame Shift Del (DEL) | VAF 68/222 reads (31%) | called by mutect2, pindel, varscan2
- RUFY3 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SCLY | c.224C>G p.A75G (on ENST00000651534; = p.A67G on NM_016510.7) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.378); called by muse, mutect2
- SH3KBP1 | c.1186C>G p.P396A | Missense Mutation (SNP) | VAF 76/96 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHANK1 | c.2394C>G p.Y798* | Nonsense Mutation (SNP) | VAF 97/319 reads (30%) | called by muse, mutect2, varscan2
- TFR2 | c.2110C>A p.R704S | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- UFSP2 | c.1190T>C p.V397A | Missense Mutation (SNP) | VAF 96/300 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- XIRP2 | c.247A>C p.K83Q | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- COL24A1 | c.873A>C p.P291= | Silent (SNP) | VAF 63/193 reads (33%) | called by muse, mutect2, varscan2
- CRB2 | c.696C>T p.C232= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- ECM1 | c.1404C>T p.F468= | Silent (SNP) | VAF 36/150 reads (24%) | called by muse, mutect2, varscan2
- KDM2B | c.3201G>A p.R1067= | Silent (SNP) | VAF 94/233 reads (40%) | catalogued as COSV100997629; called by muse, mutect2, varscan2
- LRFN4 | c.54G>A p.P18= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as rs1164265934; called by muse, mutect2, varscan2
- POF1B | c.1380C>T p.Y460= | Silent (SNP) | VAF 122/153 reads (80%) | called by muse, mutect2, varscan2
- SVOPL | c.154C>T p.L52= | Silent (SNP) | VAF 34/126 reads (27%) | called by muse, mutect2, varscan2
- UBASH3A | c.933C>T p.D311= | Silent (SNP) | VAF 75/235 reads (32%) | catalogued as rs749658882; called by muse, mutect2, varscan2
- AC074141.1 | n.2299G>A | RNA (SNP) | VAF 131/479 reads (27%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.*527A>C | 3'UTR (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- AP001007.2 | n.581T>C | RNA (SNP) | VAF 37/105 reads (35%) | called by muse, mutect2, varscan2
- ASCC1 | chr10:72216950 G>A | 5'Flank (SNP) | VAF 17/48 reads (35%) | catalogued as rs1013634699; called by muse, mutect2, varscan2
- BMP7 | c.-498C>A | 5'UTR (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- C19orf18 | c.-57A>G | 5'UTR (SNP) | VAF 27/43 reads (63%) | called by mutect2, varscan2
- CD38 | c.*847A>T | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- CDS2 | c.*1978C>G | 3'UTR (SNP) | VAF 34/50 reads (68%) | catalogued as rs1462504927; called by muse, mutect2, varscan2
- COA1 | c.-38-779T>A | Intron (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- CRYGN | c.-68G>A | 5'UTR (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- CTAGE1 | c.*804T>G | 3'UTR (SNP) | VAF 138/380 reads (36%) | called by muse, varscan2
- DNAJC16 | c.*3013G>A | 3'UTR (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- DNMBP | c.2261-21440C>G | Intron (SNP) | VAF 88/244 reads (36%) | called by muse, mutect2, varscan2
- E2F8 | c.-12G>A | 5'UTR (SNP) | VAF 65/146 reads (45%) | called by muse, mutect2, varscan2
- EIF4EBP1 | c.*398G>A | 3'UTR (SNP) | VAF 27/192 reads (14%) | called by muse, mutect2, varscan2
- FAM102A | c.-262C>T | 5'UTR (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- FAM24B | chr10:122883810 G>T | 5'Flank (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- GPRC6A | c.-7T>C | 5'UTR (SNP) | VAF 111/239 reads (46%) | called by muse, mutect2, varscan2
- GRIN2C | c.*334G>A | 3'UTR (SNP) | VAF 49/120 reads (41%) | called by muse, mutect2, varscan2
- HBB | chr11:5225392 T>G | 3'Flank (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- IL17A | c.*290C>A | 3'UTR (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- MED15 | c.208+64C>T | Intron (SNP) | VAF 39/61 reads (64%) | called by muse, mutect2, varscan2
- MEGF10 | c.*2461T>C | 3'UTR (SNP) | VAF 54/121 reads (45%) | called by muse, mutect2, varscan2
- MTO1 | chr6:73503116 del TTTATT | 3'Flank (DEL) | VAF 8/21 reads (38%) | called by mutect2, varscan2
- NKAIN1 | c.*899C>T | 3'UTR (SNP) | VAF 66/166 reads (40%) | called by muse, mutect2, varscan2
- OR4C11 | c.*189G>T | 3'UTR (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- PHACTR1 | c.104-150T>C | Intron (SNP) | VAF 79/196 reads (40%) | called by muse, mutect2, varscan2
- PHYHIPL | c.*1338T>G | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- PPARGC1A | c.*3027T>G | 3'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- PTEN | c.-648C>T | 5'UTR (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- RAB11FIP3 | c.1265+2262T>G | Intron (SNP) | VAF 40/111 reads (36%) | called by muse, mutect2, varscan2
- SELPLG | chr12:108635886 C>T | 5'Flank (SNP) | VAF 25/72 reads (35%) | catalogued as rs1346528144; called by muse, mutect2, varscan2
- SLC9A7 | c.*1133C>G | 3'UTR (SNP) | VAF 30/34 reads (88%) | called by muse, mutect2, varscan2
- SOX11 | c.-29G>A | 5'UTR (SNP) | VAF 24/64 reads (38%) | catalogued as rs1327698865; called by muse, varscan2
- SPRY3 | c.*898T>A | 3'UTR (SNP) | VAF 86/216 reads (40%) | called by muse, mutect2, varscan2
- TCTEX1D2 | chr3:196318272 C>G | 5'Flank (SNP) | VAF 10/49 reads (20%) | called by muse, varscan2
- TFEB | c.-23+9004A>T | Intron (SNP) | VAF 74/150 reads (49%) | called by muse, mutect2, varscan2
- TK2 | c.*510G>A | 3'UTR (SNP) | VAF 29/96 reads (30%) | called by muse, mutect2, varscan2
- TSPAN12 | c.*159del | 3'UTR (DEL) | VAF 26/113 reads (23%) | called by mutect2, pindel, varscan2
- UBXN2B | c.*3285C>T | 3'UTR (SNP) | VAF 63/172 reads (37%) | called by muse, mutect2, varscan2
- UBXN7 | c.*2803T>A | 3'UTR (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- ZBTB10 | c.-683A>T | 5'UTR (SNP) | VAF 156/348 reads (45%) | called by muse, mutect2, varscan2
- ZNF462 | c.*2275T>G | 3'UTR (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
